MMRF case MMRF_1916 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6a0c44b2-497f-4df1-a9e9-8102269a20f7

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.2 years (27,463 days); ISS stage: II; Days to last known disease status: 1,056 days (2.9 years); Days to last follow up: 1,056 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 370 days (1.0 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 363 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 346 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 345 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27 (ECOG 1): M Protein 1.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.731 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.19 mg/dL; Immunoglobulin G 22.5 g/L; Immunoglobulin A 0.307 g/L; Immunoglobulin M 0.241 g/L; Beta 2 Microglobulin 3.89 µg/mL; Lactate Dehydrogenase 4.25 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 8.85 ×10⁹/L; Absolute Neutrophil 4.13 ×10⁹/L; Platelets 261 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 17.9 mmol/L; Calcium 2.53 mmol/L; Albumin 38 g/L; Total Protein 8 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 0.83 mg/dL.
- Day 62 (ECOG 1): M Protein 1.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.696 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.05 mg/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.265 g/L; Beta 2 Microglobulin 3.75 µg/mL; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 3.97 ×10⁹/L; Absolute Neutrophil 2.45 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 83.1 µmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.9 g/dL; Glucose 5.39 mmol/L.
- Day 141 (ECOG 1): M Protein 1.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.139 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 0.0869 g/L; Immunoglobulin M 0.125 g/L; Beta 2 Microglobulin 3.07 µg/mL; Lactate Dehydrogenase 3.83 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 4.57 ×10⁹/L; Absolute Neutrophil 2.77 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 97.2 µmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.
- Day 258 (ECOG 1): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.061 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.006 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 0.0855 g/L; Immunoglobulin M 0.127 g/L; Lactate Dehydrogenase 3.75 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.06 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 85.7 µmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.06 mmol/L.
- Day 342 (ECOG 1): M Protein 1.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.064 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.935 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 0.0841 g/L; Immunoglobulin M 0.124 g/L; Beta 2 Microglobulin 3.17 µg/mL; Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 3.53 ×10⁹/L; Absolute Neutrophil 1.94 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 73.4 µmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.01 mmol/L.
- Day 440 (ECOG 1): M Protein 1.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.099 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 0.104 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 3.35 µg/mL; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.13 ×10⁹/L; Absolute Neutrophil 1.81 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 93.7 µmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 5.01 mmol/L.
- Day 524 (ECOG 1): M Protein 1.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 17.9 g/L; Immunoglobulin A 0.205 g/L; Immunoglobulin M 0.291 g/L; Beta 2 Microglobulin 3.72 µg/mL; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.26 ×10⁹/L; Absolute Neutrophil 2.16 ×10⁹/L; Platelets 224 ×10⁹/L; Creatinine 75.1 µmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.5 g/dL; Glucose 5.28 mmol/L.
- Day 594 (ECOG 1): M Protein 2.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.502 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 0.179 g/L; Immunoglobulin M 0.216 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.15 ×10⁹/L; Absolute Neutrophil 2.41 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 85.7 µmol/L; Calcium 2.35 mmol/L; Albumin 42.1 g/L; Total Protein 7.92 g/dL; Glucose 5.06 mmol/L.
- Day 717 (ECOG 1): M Protein 1.55 g/dL; Immunoglobulin G 19.8 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.23 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 86.6 µmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 7.5 g/dL; Glucose 4.9 mmol/L.
- Day 773 (ECOG 1): M Protein 1.52 g/dL; Immunoglobulin G 19.6 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.53 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 76.9 µmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 4.57 mmol/L.
- Day 864 (ECOG 1): M Protein 1.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.508 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 20.3 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.52 ×10⁹/L; Absolute Neutrophil 1.99 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 80.4 µmol/L; Calcium 2.33 mmol/L; Albumin 41.1 g/L; Total Protein 7.6 g/dL; Glucose 4.51 mmol/L.
- Day 976 (ECOG 1): M Protein 1.78 g/dL; Immunoglobulin G 24.9 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.53 ×10⁹/L; Absolute Neutrophil 2.04 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 76.9 µmol/L; Calcium 2.33 mmol/L; Albumin 43.2 g/L; Total Protein 8 g/dL; Glucose 5.17 mmol/L.
- Day 1,056 (ECOG 1): M Protein 1.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.432 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 25.9 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.18 ×10⁹/L; Absolute Neutrophil 1.77 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 76.9 µmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 8.1 g/dL; Glucose 4.79 mmol/L.

Other clinical attributes
- Day -27: Weight: 61 kg; Height: 146 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1916_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_1916_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
